Somatic mutation profile of tumor specimen TCGA-3A-A9IR-01A (aliquot TCGA-3A-A9IR-01A-11D-A38G-08) from TCGA case TCGA-3A-A9IR, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 64.1 years (23,406 days).
Specimen TCGA-3A-A9IR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 749f8a1a-2e00-45f9-a938-e8931ce95522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IR-10A (Blood Derived Normal), aliquot TCGA-3A-A9IR-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7e5545f-2947-40bc-85f5-103aa9fa16f0

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPK1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 117/246 reads (48%) | catalogued as rs767945252, COSV50894878, COSV50896361; called by muse, mutect2, varscan2
- KMT2D | c.1549del p.E517Sfs*413 | Frame Shift Del (DEL) | VAF 113/279 reads (41%) | catalogued as COSV99986285; called by mutect2, pindel, varscan2
- PCDHA6 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 317/712 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV65350771; called by muse, mutect2, varscan2
- REXO5 | c.2006G>A p.G669D | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV99759317; called by muse, mutect2, varscan2
- STXBP5L | c.2852T>C p.I951T | Missense Mutation (SNP) | VAF 234/479 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs1473320275, COSV99875220; called by muse, mutect2, varscan2
- THBS3 | c.1666A>G p.N556D | Missense Mutation (SNP) | VAF 257/557 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100857663; called by muse, mutect2, varscan2
- TLR5 | c.1437C>G p.F479L | Missense Mutation (SNP) | VAF 229/501 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV100643338; called by muse, mutect2, varscan2
- TUBGCP4 | c.1946T>G p.L649R (on ENST00000260383 / NM_001286414.3; = p.L648R on NM_014444.5) | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99539206; called by muse, mutect2
- ZMYM3 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV100078126; called by muse, mutect2, varscan2
- ACSS1 | c.1683G>T p.G561= | Silent (SNP) | VAF 175/388 reads (45%) | catalogued as COSV100053869; called by muse, mutect2, varscan2
- CHRNB1 | c.186A>G p.Q62= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV99548412; called by muse, mutect2, varscan2
- DGKK | c.186T>C p.A62= | Silent (SNP) | VAF 252/514 reads (49%) | catalogued as COSV101053112; called by muse, mutect2, varscan2
- GLI3 | c.3390C>T p.D1130= | Silent (SNP) | VAF 167/478 reads (35%) | catalogued as rs756608797, COSV67885638; called by muse, mutect2, varscan2
- GPR27 | c.591G>A p.T197= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1262250234, COSV55203434, COSV99816543; called by muse, mutect2
- L3HYPDH | c.129T>C p.S43= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs1338941786, COSV99711672; called by muse, mutect2, varscan2
- NRP1 | c.1095C>T p.N365= | Silent (SNP) | VAF 272/576 reads (47%) | catalogued as rs767999607, COSV55171117; called by muse, mutect2, varscan2
- SPTB | c.3315T>C p.G1105= | Silent (SNP) | VAF 76/184 reads (41%) | catalogued as COSV101072289; called by muse, mutect2, varscan2
- TMC4 | c.2103C>T p.R701= (on ENST00000617472 / NM_001145303.3; = p.R695= on NM_144686.4) | Silent (SNP) | VAF 155/355 reads (44%) | catalogued as rs77135688; called by muse, mutect2, varscan2
